Surgical pathology report (de-identified scan), TCGA case TCGA-UW-A7GP, project TCGA-KICH (Kidney Chromophobe), tissue source site University of North Carolina, specimen TCGA-UW-A7GP-01A (Primary Tumor).

[page 1 of 3]
ICD-O-3
Carcinoma, renal cell
Chromophobe type 8317/3
Site (L) Kidney NOS C64.9
9/24/13

Surgical Pathology Report

Diagnosis:

Kidney, left, laparoscopic nephrectomy

- Renal cell carcinoma, chromophobe type, grade 3 (of 4, Fuhrman classification), 11 cm diameter, without angiolymphatic invasion, without extracapsular extension, inked surgical margins not involved

Clinical History:

The patient is a year-old male with a left renal mass who now undergoes hand-assisted laparoscopic left nephrectomy.

Gross Description:

Received is one appropriately labeled container.

Specimen A is received in a container additionally labeled "left kidney".

Specimen fixation: formalin

Type of specimen: radical nephrectomy, laparoscopic

Side of specimen: left

Size and weight of specimen: size = 15 x 10.5 x 7.8 cm; weight = 900 gm

Presence/absence of adrenal gland: adrenal gland is absent

Tumor description/site: The tumor involves both upper and lower poles of the kidneys; the kidney also involves the cortex and medulla and appears to compress the renal pelvis; the tumor is tan in color; tumor is solid with small amounts of hemorrhage present; the center of the tumor appears necrotic.

Tumor size: 11 x 9 x 7.5 cm

Presence/absence of multicentricity: absent; there is only one focus of tumor

Confinement/non-confinement to the kidney: The tumor is confined to the kidney; this is supported by the fact that the tumor capsule is freely mobile and is slipping away from the bivalved surface.

Extent of invasion:

Perirenal adipose tissue: tumor does not grossly involve

Gerota's fascia: tumor does not grossly involve

[page 2 of 3]
Renal vein: tumor does not grossly involve
Ureter: tumor does not grossly involve
Other organs: no other organs present

Surgical margins:

Perirenal adipose tissue: negative
Renal vein: negative
Renal artery: negative
Ureter: negative

Description of kidney away from tumor: The renal parenchyma in the lower pole of the kidney appears slightly hemorrhagic and congested without a distinct corticomedullary junction; the remaining renal parenchyma in the upper pole of the kidney appears more normal with a definable corticomedullary junction. There is no evidence of cysts or hydronephrosis present.

Lymph nodes (hilar): none are identifiable

Other significant findings:

Tissue submitted for special investigations: none

Digital photograph taken:

Block Summary:

A1 - ureteral, arterial and venous margin
A2 - tumor in relation to capsule
A3-A4 - representative sections of tumor, capsule, and normal renal parenchyma
A5-A10 - representative sections of tumor
A11 - normal renal parenchyma

Grossing Pathologist: , M.D.

Light Microscopy: Light microscopic examination is performed by Dr.

Histologic tumor type/subtype: renal cell carcinoma, chromophobe subtype.
CD117 foc pos, CD10 foc pos Dr. concurs.

Histologic grade (if applicable): 3

Tumor size (greatest dimension): 11 cm

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: no
Gerota's fascia: not identified

[page 3 of 3]
Renal vein: not involved

Ureter: not involved

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Depth of invasion: n/a

Adjacent organs: not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative

Gerota's fascia: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Adrenal gland: not received

Lymph nodes: not received

Other significant findings: none

AJCC Staging:

pT2 pNx pMx

Source: NCI Genomic Data Commons file 6ecc7cd4-fa5c-47e3-90a7-2ca140366a3a (TCGA-UW-A7GP.AD89F764-5C47-4155-A062-CE97CBB81E39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).